Somatic mutation profile of tumor specimen TCGA-DU-6393-01A (aliquot TCGA-DU-6393-01A-11D-1705-08) from TCGA case TCGA-DU-6393, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 66.5 years (24,282 days).
Specimen TCGA-DU-6393-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fd1d36a-e4c6-438d-8ef5-3ac0ddf1663d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6393-10A (Blood Derived Normal), aliquot TCGA-DU-6393-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8afc5f2-fe01-41a9-9cbd-183aaf0f60cf

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Intron 1, In Frame Ins 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MTOR | c.6981G>A p.M2327I | Missense Mutation (SNP) | VAF 37/50 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs878855328, COSV63868602, COSV63869693, COSV63874461; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM10 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53051083; called by muse, mutect2, varscan2
- ASB17 | c.554T>C p.I185T | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs750458762, COSV52410122; called by muse, mutect2, varscan2
- BFSP2 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749419128, COSV56588172; called by muse, mutect2, varscan2
- CRAT | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs747989201, COSV58876436; called by muse, mutect2, varscan2
- DIS3L2 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1335491905, COSV56051355; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNIP1 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV57195537; called by muse, mutect2, varscan2
- GLIS3 | c.2090G>C p.S697T | Missense Mutation (SNP) | VAF 39/40 reads (98%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV60927808; called by muse, mutect2, varscan2
- GRIN2B | c.3985C>T p.R1329* | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | catalogued as rs1555101805, COSV74205614; called by muse, mutect2, varscan2
- HEATR3 | c.1862C>T p.S621L | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs771865501, COSV53528993; called by muse, mutect2, varscan2
- INSL5 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs146406445; called by muse, mutect2, varscan2
- MKRN1 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV55436389; called by muse, mutect2
- NOS2 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.871); catalogued as COSV58223272; called by muse, mutect2, varscan2
- NPAP1 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT tolerated (0.42); PolyPhen benign (0.307); catalogued as COSV61506238, COSV61508049; called by muse, mutect2, varscan2
- OR10S1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 91/155 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV73342752; called by muse, mutect2, varscan2
- PCDH11Y | c.3998C>T p.P1333L | Missense Mutation (SNP) | VAF 56/61 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV53079267; called by muse, mutect2, varscan2
- RELN | c.6734C>T p.P2245L | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs751836602, COSV58997883; called by muse, mutect2, varscan2
- SDK2 | c.1297A>G p.I433V | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.086); catalogued as COSV66184807; called by muse, mutect2
- TCHH | c.329T>C p.L110S | Missense Mutation (SNP) | VAF 100/177 reads (56%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.039); catalogued as rs778393724, COSV64274264; called by muse, mutect2, varscan2
- CIC | c.2973_2974del p.Q992Afs*158 | Frame Shift Del (DEL) | VAF 18/32 reads (56%) | called by pindel, varscan2
- QSER1 | c.2413_2415dup p.L805dup (on ENST00000399302; = p.L934dup on NM_001076786.3) | In Frame Ins (INS) | VAF 35/132 reads (27%) | called by mutect2, pindel, varscan2
- TRAV41 | c.233A>G p.H78R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1G | c.2880C>T p.V960= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs1375765527, COSV61725062; called by muse, mutect2, varscan2
- FCRL1 | c.1200G>A p.G400= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV63824863; called by muse, mutect2, varscan2
- HRNR | c.7038T>A p.S2346= | Silent (SNP) | VAF 86/1380 reads (6%) | catalogued as COSV64257072; called by muse, mutect2
- KLF14 | c.570T>C p.P190= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs953768937, COSV60588636; called by muse, mutect2
- TAF1L | c.4888T>C p.L1630= | Silent (SNP) | VAF 153/164 reads (93%) | catalogued as COSV54260936; called by muse, mutect2, varscan2
- TNFRSF11B | c.126C>T p.D42= | Silent (SNP) | VAF 94/225 reads (42%) | catalogued as COSV52070627; called by muse, mutect2, varscan2
- ZBTB20 | c.1563C>T p.P521= (on ENST00000474710 / NM_001164342.2; = p.P448= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV61848428; called by muse, mutect2, varscan2
- TTN | c.10360+3736C>T | Intron (SNP) | VAF 67/136 reads (49%) | catalogued as rs774617179, COSV100612784; called by muse, mutect2, varscan2
